FM case AD14203 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/c0eaa809-6631-4dc8-af1e-b76ab463ab9f

Male, 60.0 years: Adenocarcinoma, diffuse type (ICD-O-3 8145/3) of the stomach; metastasis. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
